Surgical pathology report (de-identified scan), TCGA case TCGA-YU-A94L, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-YU-A94L-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

ICD-O-3
Seminoma NOS 9061/3
Site (B) Testis NOS
C62.9
JW 2/2/14

PATHOLOGY REPORT:

PRIMARY SITE: Right testis

“Right testis and spermatic cord”:

- Classic seminoma.
- Neoplasia size: 3.7 x 3.3 x 2.8cm.
- Sanguineous vascular invasion: not detected.
- Lymphatic vascular invasion: not detected.
- Perineural invasion: not detected.
- Intratubular neoplasia: present.
- Rete testis: involved by neoplasia.
- Tunica albuginea: uninvolved by neoplasia.
- Spermatic cord: uninvolved by neoplasia.
- Adjacent testicular parenchyma: within normal limits.
- Margin of spermatic cord: uninvolved by neoplasia.
-

“Genital wart”:

- Viral wart.

Site AA Discrepancy		✓

Source: NCI Genomic Data Commons file 5827318e-ee9e-46be-b7ac-e3303015f8d1 (TCGA-YU-A94L-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).